Somatic mutation profile of tumor specimen TCGA-CA-5796-01A (aliquot TCGA-CA-5796-01A-01D-1650-10) from TCGA case TCGA-CA-5796, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.0 years (19,353 days).
Specimen TCGA-CA-5796-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 565f7fa6-ec36-4c01-ba34-6540c4ae7d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-5796-10A (Blood Derived Normal), aliquot TCGA-CA-5796-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b088c5c2-d382-41aa-9d23-1333107d9d03

The open-access MAF lists 76 somatic variants for this specimen: 54 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 21, Nonsense Mutation 5, Splice Site 2, Splice Region 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1555398835, CM074810, COSV57309410; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 112/264 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as rs778235410, CM012179, COSV52936442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 112/285 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61685165, COSV61693805, COSV61696029; called by muse, mutect2, varscan2
- AKR7A3 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs753206965, COSV64388940; called by muse, mutect2, varscan2
- CARD11 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs201948130, COSV62756769; ClinVar: not provided; called by muse, varscan2
- CCDC28B | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99356563; called by muse, mutect2
- COL11A2 | c.1307T>C p.L436P (on ENST00000341947 / NM_080680.3; = p.L329P on NM_080679.2) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100553980; called by muse, mutect2, varscan2
- CT55 | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1556404485, COSV99358869; called by muse, mutect2, varscan2
- DNAH9 | c.13435G>T p.G4479* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV52371999; called by muse, mutect2, varscan2
- DSCAML1 | c.1676G>A p.R559Q (on ENST00000321322; = p.R499Q on NM_020693.4) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1484664737, COSV58396830; called by muse, mutect2, varscan2
- DSP | c.7994C>T p.T2665M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs151309106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EMG1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555152823, COSV54642042; called by muse, mutect2, varscan2
- ENPEP | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1341121359, COSV54452042; called by muse, mutect2, varscan2
- EP300 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs886057557, COSV54336678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.4337G>A p.G1446E | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.163); catalogued as COSV64277748; called by muse, mutect2, varscan2
- FAM114A1 | c.438T>G p.G146= | Splice Region (SNP) | VAF 72/202 reads (36%) | catalogued as COSV62674538; called by muse, mutect2, varscan2
- FAM114A1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV62674545; called by muse, mutect2, varscan2
- FAT4 | c.5968G>A p.G1990R | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV100628574; called by muse, mutect2, varscan2
- FLT4 | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778806900, COSV56105548, COSV99988729; called by muse, mutect2, varscan2
- GPR19 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60124480; called by muse, mutect2, varscan2
- IFIH1 | c.2305-1G>T p.X769_splice | Splice Site (SNP) | VAF 226/561 reads (40%) | catalogued as COSV55128960, COSV55129568; called by muse, mutect2, varscan2
- INSL4 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 71/121 reads (59%) | catalogued as rs377326081; called by muse, mutect2, varscan2
- IQCA1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs201684914; called by muse, mutect2, varscan2
- IQCN | c.2244_2246del p.I749del | In Frame Del (DEL) | VAF 13/29 reads (45%) | catalogued as COSV66577062; called by mutect2, pindel, varscan2
- ISM1 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52607479; called by muse, mutect2
- ITGA4 | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 80/391 reads (20%) | catalogued as COSV52003383; called by muse, mutect2, varscan2
- LTBP2 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199710871, COSV100000299; called by muse, mutect2, varscan2
- MATR3 | c.1715A>G p.Y572C | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100735206; called by muse, mutect2, varscan2
- MED12 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs199469668, COSV61330895; ClinVar: not provided; called by muse, varscan2
- MFSD12 | c.1433C>G p.A478G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.018); catalogued as COSV100281370; called by muse, mutect2, varscan2
- MYOM1 | c.4341C>T p.A1447= | Splice Region (SNP) | VAF 97/202 reads (48%) | catalogued as rs1453531530, COSV99866630; called by muse, mutect2, varscan2
- NLRP4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.534); catalogued as rs768142392, COSV56712077; called by muse, mutect2, varscan2
- PALMD | c.1646dup p.V550Gfs*10 | Frame Shift Ins (INS) | VAF 291/909 reads (32%) | catalogued as rs763559641; called by mutect2, pindel, varscan2
- PIAS4 | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53680823; called by muse, mutect2
- PIWIL1 | c.1866+1G>A p.X622_splice | Splice Site (SNP) | VAF 38/172 reads (22%) | catalogued as rs761727169, COSV55348179; called by muse, mutect2, varscan2
- PPM1E | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1023376960, COSV57577448; called by muse, mutect2
- PUM3 | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV65896917; called by muse, mutect2, varscan2
- RELN | c.9826G>A p.A3276T | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs781713047, COSV100633679; called by muse, mutect2, varscan2
- RTBDN | c.494C>T p.S165L (on ENST00000393233 / NM_001270444.1; = p.S197L on NM_031429.2) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as rs1202334753, COSV59807046; called by muse, mutect2
- S1PR4 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs770488747, COSV55740657; called by muse, mutect2, varscan2
- SGSM2 | c.1427G>C p.S476T (on ENST00000426855 / NM_001098509.2; = p.S521T on NM_014853.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.061); catalogued as COSV99280127; called by muse, varscan2
- SHANK3 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53190428; called by muse, mutect2, varscan2
- SLC41A3 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV59988501; called by muse, mutect2, varscan2
- SLC5A2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs760532652, COSV57894019; called by muse, mutect2, varscan2
- SORCS3 | c.2735G>T p.C912F | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV63797902; called by muse, mutect2, varscan2
- SYNPO2 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs375410311, COSV61106195; called by muse, mutect2, varscan2
- THOC2 | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 211/584 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as COSV55554111; called by muse, mutect2, varscan2
- TMEM215 | c.203A>T p.K68M | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV100713180; called by muse, mutect2, varscan2
- TNIP3 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.058); catalogued as COSV50252790; called by muse, mutect2
- TSHZ2 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as COSV61589437; called by muse, mutect2, varscan2
- TTN | c.60683T>C p.M20228T (on ENST00000591111; = p.M12804T on NM_003319.4) | Missense Mutation (SNP) | VAF 72/211 reads (34%) | PolyPhen benign (0.295); catalogued as COSV60288413; called by muse, mutect2
- WSCD2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54592899; called by muse, mutect2, varscan2
- ZFHX4 | c.2129C>A p.T710N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51490513; called by muse, mutect2, varscan2
- CCBE1 | c.708C>T p.D236= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs766503507, COSV67951284; called by muse, mutect2, varscan2
- DNAH8 | c.5913T>C p.A1971= | Silent (SNP) | VAF 83/215 reads (39%) | catalogued as COSV59474580; called by muse, mutect2, varscan2
- FAM214B | c.271C>T p.L91= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59717334; called by muse, mutect2, varscan2
- FLRT2 | c.1599G>A p.T533= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV58144895; called by muse, mutect2, varscan2
- GCNA | c.51C>T p.D17= | Silent (SNP) | VAF 197/524 reads (38%) | catalogued as rs377049000, COSV65468016; called by muse, mutect2, varscan2
- GHR | c.723C>T p.G241= | Silent (SNP) | VAF 90/213 reads (42%) | catalogued as rs1260870046, CS971752, COSV50126124; called by muse, mutect2, varscan2
- GNAI3 | c.315G>A p.R105= | Silent (SNP) | VAF 15/352 reads (4%) | catalogued as COSV100879876; called by muse, mutect2
- HEYL | c.474C>T p.A158= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs372712511; called by muse, mutect2, varscan2
- KANK2 | c.1050C>T p.P350= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs143966820, COSV100763198; called by muse, mutect2, varscan2
- LAMB2 | c.3000T>C p.C1000= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV59737314; called by muse, mutect2
- MISP | c.1983G>A p.K661= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV53121956; called by muse, mutect2, varscan2
- OR5D14 | c.669T>A p.I223= | Silent (SNP) | VAF 123/321 reads (38%) | catalogued as COSV59458165; called by muse, mutect2, varscan2
- PEAR1 | c.2850C>A p.P950= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV52775432; called by muse, mutect2, varscan2
- PPARD | c.828C>T p.N276= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs751619761, COSV61101241; called by muse, mutect2, varscan2
- PREX2 | c.1380T>C p.Y460= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV55809997; called by muse, mutect2, varscan2
- SCN10A | c.5712A>G p.V1904= | Silent (SNP) | VAF 37/332 reads (11%) | catalogued as COSV101479380; called by muse, mutect2, varscan2
- SLC4A5 | c.2379C>T p.I793= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs369488308; called by muse, mutect2, varscan2
- SLC6A4 | c.1200C>T p.D400= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs148279474; called by muse, mutect2, varscan2
- TTC6 | c.1458A>G p.V486= (on ENST00000267368; = p.V1852= on NM_001310135.3) | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as COSV57452406; called by muse, mutect2, varscan2
- WASHC2A | c.2028T>C p.I676= | Silent (SNP) | VAF 132/314 reads (42%) | called by muse, mutect2, varscan2
- ZNF341 | c.858C>T p.T286= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs762729020, COSV61010829; called by muse, mutect2, varscan2
- ARPP21 | c.2032+532G>A | Intron (SNP) | VAF 24/33 reads (73%) | catalogued as rs1273290796, COSV51800624; called by muse, mutect2, varscan2
